Somatic mutation profile of tumor specimen TCGA-LN-A49N-01A (aliquot TCGA-LN-A49N-01A-11D-A247-09) from TCGA case TCGA-LN-A49N, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 50.7 years (18,503 days).
Specimen TCGA-LN-A49N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89247478-254a-4bab-9683-22a692ab6bfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49N-10A (Blood Derived Normal), aliquot TCGA-LN-A49N-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbe018d4-bf1a-4cf9-92b5-e4b32dd3fca5

The open-access MAF lists 61 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, Frame Shift Ins 4, Nonsense Mutation 3, Frame Shift Del 3, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.754del p.L252Sfs*93 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as rs1555525470, COSV52730003; ClinVar: pathogenic; called by mutect2, pindel*, varscan2
- ABCB8 | c.11A>G p.H4R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as rs751158127; called by muse, mutect2, varscan2
- ACAD11 | c.1707G>A p.M569I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1156877745; called by muse, mutect2, varscan2
- ANO6 | c.121A>T p.S41C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV57656881; called by muse, mutect2, varscan2
- BLNK | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs782667010, COSV56412399; called by muse, mutect2
- CHRD | c.1559C>A p.A520D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.175); catalogued as COSV52612429; called by muse, mutect2, varscan2
- CSMD1 | c.3487G>T p.G1163* (on ENST00000520002; = p.G1162* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV59311148; called by muse, mutect2
- DNAH8 | c.8609G>C p.G2870A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1561844722; called by muse, varscan2
- ERCC2 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs760834335, COSV67263587; called by muse, mutect2, varscan2
- FAM149A | c.1525G>A p.D509N (on ENST00000356371 / NM_001367768.2; = p.D218N on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as rs369514269; called by muse, mutect2, varscan2
- LRRC32 | c.1729G>A p.G577S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.212); catalogued as COSV52632161; called by muse, mutect2, varscan2
- MATN2 | c.2179T>C p.Y727H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs554199301; called by muse, mutect2, varscan2
- PML | c.2017A>G p.I673V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs367820386; called by muse, varscan2
- POTEH | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as rs758952557, COSV58883447; called by muse, mutect2, varscan2
- SATB1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs751519264, COSV58667132; called by muse, mutect2, varscan2
- SEC24B | c.1597A>G p.I533V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1241471243; called by muse, mutect2, varscan2
- STXBP5 | c.1102C>A p.L368I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99469935; called by muse, mutect2
- TGFBR2 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV55447425, COSV99846750; called by muse, mutect2, varscan2
- ANGPT4 | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ATG7 | c.758C>A p.A253D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- BNC2 | c.2743G>C p.E915Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CDC27 | c.422G>C p.S141T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CFAP46 | c.266G>T p.C89F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- COPB2 | c.2590A>G p.I864V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DDX23 | c.1375A>G p.I459V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- DDX60 | c.5130C>G p.N1710K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH3 | c.2288T>C p.V763A | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERP27 | c.464_476del p.L155* | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- ETFDH | c.1121dup p.P375Tfs*14 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- FANCI | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXO11 | c.2194_2195dup p.D732Efs*38 (on ENST00000403359 / NM_001190274.2; = p.D648Efs*38 on NM_025133.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- FTO | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- IRX6 | c.578T>A p.V193E | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP6 | c.2732del p.G911Vfs*38 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- MINAR1 | c.2191A>T p.R731* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- MRAS | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.2372C>G p.P791R | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- NLRP1 | c.1379C>A p.T460N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NOTCH1 | c.3364T>A p.C1122S | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- RFX7 | c.-1_1dup p.M1? (on ENST00000559447 / NM_001368074.1; = p.M98Tfs*20 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- SNTG2 | c.715T>A p.L239I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- STRAP | c.340T>G p.Y114D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TAAR9 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- UBE2T | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ZBED1 | c.592_598delinsG p.T198_M200delinsV | In Frame Del (DEL) | VAF 25/70 reads (36%) | called by pindel, varscan2*
- ZNF527 | c.112_118dup p.R40Ifs*22 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- AC008676.3 | c.396C>T p.C132= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- ANKRD27 | c.568C>T p.L190= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs1324482174; called by muse, mutect2, varscan2
- ATM | c.7881T>C p.Y2627= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- HOXA3 | c.753G>A p.K251= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs1247136179; called by muse, mutect2, varscan2
- LENG8 | c.1686G>C p.L562= | Silent (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- LIPH | c.288C>G p.L96= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- MACF1 | c.3001C>T p.L1001= | Silent (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- MYO1B | c.3042T>C p.N1014= (on ENST00000304164; = p.N956= on NM_012223.5) | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- NAIF1 | c.537G>A p.T179= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs757109726; called by muse, mutect2, varscan2
- OR4Q3 | c.315A>G p.G105= | Silent (SNP) | VAF 13/143 reads (9%) | called by muse, mutect2
- S100A12 | c.132C>A p.T44= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- THSD7A | c.2712G>A p.Q904= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1157482558; called by muse, mutect2
- TTN | c.28176C>T p.V9392= (on ENST00000591111; = p.V8465= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs769063245, COSV59881298; called by muse, mutect2, varscan2
- UNC13D | c.2547C>T p.A849= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1192923237; called by muse, mutect2, varscan2
- MIR519A1 | n.52G>A | RNA (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
